Gene-level copy-number profile of specimen HCM-CSHL-0382-C19-85A from HCMI case HCM-CSHL-0382-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 68.0 years (24,847 days).
Specimen HCM-CSHL-0382-C19-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0999e2a8-6545-47e6-b38a-d475f7614009.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0382-C19-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/e1b40f5f-90ac-43f9-aaa0-399b20d86e5f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 1,128; copy number 2: 28,643; copy number 3: 24,847; copy number 4: 2,417; copy number 5: 1,363; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:14,933,843–15,022,958, 3 genes (within-gene range 0–3): AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,365 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:4,905,989–41,133,507, 613 genes, copy number 5 (broad region; genes not listed).
- chr7:45,574,140–53,947,804, 93 genes, copy number 5 (broad region; genes not listed).
- chr13:85,065,087–114,337,626, 376 genes, copy number 5 (broad region; genes not listed).
- chr17:18,426,861–18,475,920, 6 genes, copy number 5: KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2.
- chr20:87,250–13,996,443, 277 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,127. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
